Somatic mutation profile of tumor specimen 0E0QXM from CCDI case PBCVPR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0QXM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e4d559b-4a62-4e3c-877f-c9bafd45de7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0QY7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a1c2d59-d01c-4b39-8859-69f34043ea12

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF7 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 287/672 reads (43%) | catalogued as rs1235928535, CM113621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.5540C>T p.T1847M | Missense Mutation (SNP) | VAF 499/1179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371686531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLG5 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 371/796 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1046674552, COSV64947139; called by muse, mutect2, varscan2
- FGD5 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 446/1131 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs375231003; called by muse, mutect2, varscan2
- ITGB7 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 313/685 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs574474249; called by muse, mutect2, varscan2
- PCDHGB2 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 424/824 reads (51%) | catalogued as COSV53950376; called by muse, mutect2, varscan2
- PSG9 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 272/529 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755539714, COSV52485807; called by muse, mutect2, varscan2
- SAMD9L | c.3562C>T p.R1188* | Nonsense Mutation (SNP) | VAF 369/921 reads (40%) | catalogued as rs572865269, COSV59079092; called by muse, mutect2, varscan2
- SENP6 | c.1325G>A p.S442N | Missense Mutation (SNP) | VAF 643/1496 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs373023926, COSV100519448; called by muse, mutect2, varscan2
- SERINC2 | c.160A>G p.I54V (on ENST00000373709 / NM_178865.5; = p.I58V on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 601/1290 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs782815579; called by muse, mutect2, varscan2
- SLC24A4 | c.1254G>A p.P418= | Splice Region (SNP) | VAF 355/792 reads (45%) | catalogued as rs761242671, COSV54107132; called by muse, mutect2, varscan2
- ZNF98 | c.460T>G p.F154V | Missense Mutation (SNP) | VAF 258/689 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV63339468; called by muse, varscan2
- DSG2 | c.2540T>G p.I847R | Missense Mutation (SNP) | VAF 426/946 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HMGN5 | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 382/914 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM3B | c.5107G>T p.D1703Y | Missense Mutation (SNP) | VAF 505/1246 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP4K4 | c.560C>A p.T187K | Missense Mutation (SNP) | VAF 417/1011 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYCT1 | c.86dup p.D30Rfs*22 | Frame Shift Ins (INS) | VAF 638/1520 reads (42%) | called by mutect2, varscan2
- MYOF | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 264/657 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRKAR1A | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 1516/1582 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A3 | c.1391C>G p.P464R | Missense Mutation (SNP) | VAF 504/1207 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- UBR2 | c.4180G>A p.A1394T | Missense Mutation (SNP) | VAF 310/726 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, varscan2
- C12orf56 | c.18G>A p.P6= | Silent (SNP) | VAF 232/467 reads (50%) | catalogued as rs1440733918; called by muse, mutect2, varscan2
- DCST2 | c.1254C>T p.L418= | Silent (SNP) | VAF 411/901 reads (46%) | catalogued as rs558786322; called by muse, mutect2, varscan2
- DISP2 | c.1137C>T p.A379= | Silent (SNP) | VAF 113/259 reads (44%) | called by muse, mutect2, varscan2
- HACE1 | c.2064G>A p.A688= | Silent (SNP) | VAF 611/1486 reads (41%) | catalogued as rs200534595, COSV53501861; called by muse, varscan2
- KAT6A | c.2433C>T p.I811= | Silent (SNP) | VAF 412/1027 reads (40%) | called by muse, mutect2, varscan2
- ZNF878 | c.735C>T p.H245= | Silent (SNP) | VAF 385/908 reads (42%) | catalogued as rs368980397; called by muse, mutect2, varscan2
- AC109583.1 | c.-543+12307C>T | Intron (SNP) | VAF 413/988 reads (42%) | catalogued as rs768999817; called by muse, mutect2, varscan2
